Somatic mutation profile of tumor specimen TCGA-CQ-5324-01A (aliquot TCGA-CQ-5324-01A-01D-1683-08) from TCGA case TCGA-CQ-5324, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 59.7 years (21,803 days).
Specimen TCGA-CQ-5324-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) daacf6d2-eb3a-4718-a6d6-061f2bba26d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-5324-10A (Blood Derived Normal), aliquot TCGA-CQ-5324-10A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc364971-01ef-4f6e-81fa-23eb02f3b376

The open-access MAF lists 72 somatic variants for this specimen: 60 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 49, Silent 12, Nonsense Mutation 3, Splice Site 3, Frame Shift Del 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.89T>A p.L30H | Missense Mutation (SNP) | VAF 20/37 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101229406, COSV67960170, COSV67961004; called by muse, mutect2, varscan2
- ADAMTS20 | c.2950G>A p.G984R | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as rs780650068, COSV101166369; called by muse, mutect2, varscan2
- ANO5 | c.1243G>C p.V415L | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100202073; called by muse, mutect2, varscan2
- ARRDC3 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as COSV99475364; called by muse, mutect2, varscan2
- ATAD3A | c.1342A>G p.N448D | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as rs747303116; called by muse, mutect2, varscan2
- ATP4B | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV100089855; called by muse, mutect2, varscan2
- AURKC | c.205G>A p.V69M (on ENST00000302804 / NM_001015878.2; = p.V35M on NM_003160.3) | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as rs1156888282, COSV100248950; called by muse, mutect2, varscan2
- C7orf57 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs761722347, COSV100817317; called by muse, mutect2, varscan2
- CACNA1H | c.5021G>A p.R1674H | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs369914175; called by muse, mutect2, varscan2
- CASP8 | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.77); catalogued as COSV51853849; called by muse, mutect2, varscan2
- CCNJ | c.764A>G p.Q255R | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT tolerated (0.15); PolyPhen benign (0.187); catalogued as COSV99796322; called by muse, mutect2, varscan2
- CCT8L2 | c.910C>T p.L304F | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100742985, COSV63461784; called by muse, mutect2, varscan2
- CDS2 | c.1083A>C p.K361N | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100986163; called by muse, mutect2, varscan2
- DNHD1 | c.14116T>A p.S4706T | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.894); catalogued as COSV99600723; called by muse, mutect2, varscan2
- DOP1A | c.3037C>T p.R1013C | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.791); catalogued as rs1457134195, COSV52714649; called by muse, mutect2, varscan2
- ELF4 | c.1541C>T p.S514F | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs753536141, COSV100257534; called by muse, mutect2, varscan2
- FNDC3B | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.229); catalogued as COSV61050729; called by muse, mutect2, varscan2
- GRIA1 | c.2050A>T p.M684L | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV99601532; called by muse, mutect2, varscan2
- GRIK5 | c.551C>G p.S184C | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV99491189; called by muse, mutect2, varscan2
- GRIN2A | c.1255G>A p.V419M | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58020274; called by muse, mutect2, varscan2
- GRM3 | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100862664, COSV100862746; called by muse, mutect2, varscan2
- HCN1 | c.2285C>T p.T762M | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.386); catalogued as rs544168876, COSV100299634, COSV57491554; called by muse, mutect2, varscan2
- HK2 | c.2483G>A p.R828Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.146); catalogued as rs148653106; called by muse, mutect2, varscan2
- KIAA0930 | c.209G>A p.G70E (on ENST00000336156 / NM_001009880.2; = p.G75E on NM_015264.2) | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.042); catalogued as COSV99325990; called by muse, mutect2, varscan2
- LATS1 | c.497-1G>A p.X166_splice | Splice Site (SNP) | VAF 19/55 reads (35%) | catalogued as COSV99486479; called by muse, mutect2, varscan2
- LRP1 | c.12011A>G p.H4004R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.492); catalogued as COSV99676753; called by muse, mutect2, varscan2
- MAP3K6 | c.3760C>T p.R1254* | Nonsense Mutation (SNP) | VAF 11/86 reads (13%) | catalogued as rs1268708547, COSV100539513; called by muse, mutect2, varscan2
- MPP4 | c.1856A>T p.Q619L | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV99636122; called by muse, mutect2, varscan2
- NBAS | c.2763+1G>T p.X921_splice | Splice Site (SNP) | VAF 14/36 reads (39%) | catalogued as COSV99871164; called by muse, mutect2
- NEDD4L | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as rs12968145, COSV99896124; called by mutect2, varscan2
- NEK8 | c.1512C>G p.I504M | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.819); catalogued as COSV52045988, COSV99262177; called by muse, mutect2, varscan2
- NPEPPS | c.785A>G p.D262G | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV100443892; called by muse, mutect2, varscan2
- NPHP3 | c.1524+1G>A p.X508_splice | Splice Site (SNP) | VAF 40/112 reads (36%) | catalogued as COSV100447231; called by muse, mutect2, varscan2
- OTOGL | c.3590G>A p.R1197K (on ENST00000547103; = p.R1188K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101509467; called by muse, mutect2, varscan2
- PRAMEF19 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 42/283 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as rs752845494; called by muse, mutect2, varscan2
- PTDSS1 | c.642G>A p.W214* | Nonsense Mutation (SNP) | VAF 55/134 reads (41%) | catalogued as COSV100428857, COSV61263621; called by muse, mutect2, varscan2
- PYGB | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201508171, COSV99405376; called by muse, mutect2, varscan2
- RAD17 | c.922A>G p.N308D (on ENST00000380774 / NM_133339.2; = p.N297D on NM_002873.1) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.079); catalogued as COSV99281680; called by muse, mutect2
- SEC11A | c.292G>C p.V98L | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV99190160; called by muse, mutect2, varscan2
- SEC14L4 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); catalogued as rs145663781; called by muse, mutect2, varscan2
- SETD2 | c.2372C>G p.S791* | Nonsense Mutation (SNP) | VAF 27/78 reads (35%) | catalogued as COSV100339717, COSV57430699, COSV57434745; called by muse, mutect2, varscan2
- SIGLEC1 | c.757C>T p.L253F | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.83); catalogued as COSV99170063; called by muse, mutect2, varscan2
- SNRNP48 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs141422613, COSV60940309; called by muse, mutect2, varscan2
- SPATA31D1 | c.4010C>G p.S1337C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as COSV100782971; called by muse, mutect2, varscan2
- TBC1D24 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760474458, CM140128, COSV99565217; called by muse, mutect2, varscan2
- TDRD10 | c.602C>T p.T201M | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs546615227, COSV99427594; called by muse, mutect2, varscan2
- TINF2 | c.851C>T p.T284I | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as CM109724, CM109727, COSV99945652; called by muse, mutect2, varscan2
- TP53BP1 | c.3796G>A p.E1266K | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV55500991, COSV99780731, COSV99781152; called by muse, mutect2, varscan2
- UGT2B10 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as rs375571968, COSV55321532; called by muse, mutect2, varscan2
- UGT3A1 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.698); catalogued as rs763080249, COSV57095004, COSV57101160, COSV99072889; called by muse, mutect2, varscan2
- YBX1 | c.857A>G p.N286S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.145); catalogued as COSV100172186; called by muse, mutect2, varscan2
- ZNF318 | c.5523G>T p.L1841F | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.962); catalogued as COSV100546424; called by muse, mutect2, varscan2
- ZNF347 | c.2162G>T p.R721L | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs150489253, COSV100498380; called by muse, mutect2, varscan2
- DST | c.3501_3504del p.Y1167* (on ENST00000361203 / NM_001374722.1; = p.Y841* on NM_001723.6) | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | called by mutect2, pindel, varscan2
- DST | c.3209_3210del p.S1070* (on ENST00000361203 / NM_001374722.1; = p.S744* on NM_001723.6) | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by pindel, varscan2
- ELF2 | c.1592del p.K531Rfs*18 (on ENST00000379550 / NM_001331036.2; = p.K471Rfs*18 on NM_006874.4) | Frame Shift Del (DEL) | VAF 52/186 reads (28%) | called by mutect2, pindel, varscan2
- HLA-B | c.849_852dup p.V285Pfs*5 | Frame Shift Ins (INS) | VAF 9/47 reads (19%) | called by mutect2, varscan2
- ITSN2 | c.3162dup p.P1055Tfs*2 | Frame Shift Ins (INS) | VAF 22/92 reads (24%) | called by mutect2, pindel, varscan2
- MACF1 | c.10633C>A p.L3545M | Missense Mutation (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2
- USP32 | c.4567G>A p.G1523S | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPLANE2 | c.321C>T p.V107= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as rs756798249, COSV65057003; called by muse, mutect2, varscan2
- DNTTIP1 | c.810C>T p.I270= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs148278422; called by muse, mutect2, varscan2
- EPN1 | c.897C>T p.P299= (on ENST00000270460 / NM_001321263.1; = p.P274= on NM_013333.3) | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99322227; called by muse, mutect2, varscan2
- HLA-DQA2 | c.663C>T p.C221= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as rs572758897, COSV66565978; called by muse, mutect2, varscan2
- IQGAP2 | c.4011G>A p.T1337= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs748724577, COSV99167824; called by muse, mutect2, varscan2
- MARK2 | c.840G>A p.L280= | Silent (SNP) | VAF 106/310 reads (34%) | catalogued as COSV100159026; called by muse, mutect2, varscan2
- MARK4 | c.747C>T p.L249= | Silent (SNP) | VAF 82/137 reads (60%) | catalogued as rs140158030; called by muse, mutect2, varscan2
- NDST1 | c.327C>T p.F109= | Silent (SNP) | VAF 28/117 reads (24%) | catalogued as COSV99939018; called by muse, mutect2, varscan2
- PAN3 | c.741A>T p.G247= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV101111158; called by muse, mutect2
- PTCHD4 | c.2184C>T p.H728= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs761246460, COSV100261392; called by muse, varscan2
- TPPP2 | c.183C>T p.N61= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs202091704, COSV100409634; called by muse, mutect2, varscan2
- TTC3 | c.3822C>G p.V1274= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as COSV100695884; called by muse, mutect2, varscan2
